Gene-level copy-number profile of tumor specimen TCGA-XF-A8HD-01A from TCGA case TCGA-XF-A8HD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 77.5 years (28,305 days).
Specimen TCGA-XF-A8HD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c1e99369-b029-45a1-9126-209355c04ca2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-A8HD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f8f72b1e-154b-45d2-9749-2343c0ae0244

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 11,676; copy number 3: 25,854; copy number 4: 18,691; copy number 5: 2,703; copy number 6: 458; copy number 7: 356; copy number 12: 2; copy number 22: 55; copy number 25: 6; copy number 26: 6; copy number 29: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-A8HD-01A-11D-A363-01): tumor purity 0.43, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 427 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,790,442–14,489,349, 55 genes, copy number 22 (within-gene range 2–22): TAMM41, FANCD2P2, CYCSP12, NUP210P2, MARK2P14, AC090958.1, RN7SL147P, SYN2, ACTG1P12, TIMP4, MTCO1P5, GSTM5P1, PPARG, AC091492.1, TSEN2, RNA5SP123, RNU6-377P, MKRN2OS, MKRN2, Metazoa_SRP, RAF1, CRIP1P1, TMEM40, KRT18P17, CAND2, AC034198.2, RPL32, SNORA7A, AC034198.1, LINC02022, IQSEC1, AC069271.1, NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6.
- chr10:3,433,508–3,816,169, 6 genes, copy number 26: LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1.
- chr10:7,818,505–8,016,631, 1 gene, copy number 25 (within-gene range 3–25): TAF3.
- chr10:8,045,378–8,268,342, 5 genes, copy number 25: GATA3, GATA3-AS1, AL390294.1, PRPF38AP1, LINC00708.
- chr10:9,275,833–9,309,772, 2 genes, copy number 29: LINC00709, AL138773.1.
- chr10:11,920,022–12,043,170, 2 genes, copy number 12 (within-gene range 2–12): UPF2, RNU6-1095P.
- chr18:47,390–5,630,700, 117 genes, copy number 7 (broad region; genes not listed).
- chr18:22,347,846–39,800,322, 239 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
